Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A2CG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A2CG-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

ICD-0-3

carcinoma, perovs, NOS 8441/3

Site: endometrium C54.1

fw 6/20/11

Specimen(s) Received

1. Lymph-Node: Right and left periaortic
2. Lymph-Node: Right pelvic
3. Omentum: Biopsy
4. Uterus: Hysterectomy BSO
5. Lymph node: Left pelvic nodes

Diagnosis

1. Lymph-Node: Right and left para-aortic:
Eleven nodes, negative for carcinoma (0/11)
2. Lymph-Node: Right pelvic:
Five nodes, negative for carcinoma (0/5)
3. Omentum: Biopsy:
Negative for carcinoma
4. Uterus, cervix, bilateral tubes and ovaries, Total Hysterectomy and bilateral salpingo-oophorectomy:
UTERINE SEROUS CARCINOMA
- Invading inner half (inner third) of myometrium
- Cervix: negative for carcinoma
- Lymphovascular space invasion: negative

Tubes and ovaries, bilateral:
Negative for carcinoma
5. Lymph node: Left pelvic nodes:
Three nodes, negative for carcinoma (0/3)

Synoptic Data

[page 2 of 3]
----- MACROSCOPIC -----
Specimen Type: Total Hysterectomy
Tumor Site: Anterior endometrium
Tumor Size: Greatest dimension: 2.2 cm
Additional dimensions: 2x0.9 cm

Other Organs Present: Right ovary
Left ovary
Right fallopian tube
Left fallopian tube
Lymph nodes
Omentum

----- MICROSCOPIC -----
Histologic Type: Serous adenocarcinoma
Histologic Grade: Other: high grade
Myometrial Invasion: Invasion Present
Less than 50% myometrial invasion
Cervix Involvement: None
LUS Involvement: No
Venous/Lymphatic Invasion: Absent
Nodal Involvement: None
Margins: Uninvolved by invasive carcinoma
Primary Tumor (pT): pT1b (IB): Tumor invades less than one-half of the
myometrium
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 19
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings: None identified
NeoAdjuvant Treatment: No
Collaborative Staging Extension: Not applicable

Electronically

verified by:

Clinical History
endometrial ca

Gross Description

The specimen container labelled with the patient's name and as "right and left periaortic lymph nodes" contains 3 pieces of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures from 1.6 x 1.0 x 0.5 to 3.5 x 2.2 x 0.9 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.2 x 0.1 x 0.1 to 0.5 x 0.4 x 0.3 cm.

1A multiple lymph nodes

1B multiple lymph nodes

1C one node and the rest of the fatty tissue submitted in toto

2. The specimen container labelled with the patient's name and as "right pelvic lymph nodes" contains multiple pieces of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 0.8 x 0.6 x 0.6 to 4.5 x 2.5 x 0.8 cm. Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.2 x 0.2 x 0.1 to 0.6 x 0.5 x 0.3 cm.

[page 3 of 3]
- 2A multiple lymph nodes
- 2B two lymph nodes
- 2C the rest of the fatty tissue submitted in toto

3. The specimen container is labeled with the patient's name and as "omentum" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 22.3 x 9.2 x 1.4 cm and weighs 71.6 g.

On serial sectioning, the cut surface is predominantly fatty with no nodules identified grossly. Representative sections are submitted as follows:

3A-3E representative section submitted

4. The specimen container is labeled with the patient's name and as "uterus hysterectomy BSO" contains a uterus, cervix, bilateral fimbriated fallopian tube and bilateral ovaries received in 10% buffered formalin. The uterus measures 8.5 SI x 5.0 ML x 3.6 cm AP and the cervix measures 3.0 cm. with a 0.7 cm ovoid shaped os. The right and left fimbriated fallopian tube measures 4.0 x 0.6 cm and 4.5 x 0.5 cm respectively. The right and left ovary measures 1.4 x 1.0 x 0.7 cm and 1.8 x 1.1 x 0.6 cm respectively. The entire specimen weighs 96.0 g. On gross examination, both the right and left fimbriated fallopian tube is brown tan in color, and has multiple tiny paratubal cyst ranging in size from 0.2 x 0.1 x 0.1 to 0.2 x 0.2 x 0.2 cm filled with clear fluid. The external and the cut surface of the right and left ovary is tan in color, smooth and grossly unremarkable. Both the anterior and posterior uterine serosa is intact, and has presence of focal areas of hemorrhagic fibrous adhesions. On sectioning, a polypoid brown-tan lesion is identified predominantly seen on the superior aspect of the anterior endometrium extending to the inferior aspect measuring 2.2 SI x 2.0 ML x 0.9 cm AP. The cut surface of the lesion is tan in color and has a multinodular appearance. The myometrium has a trabeculated appearance. Multiple cystic lesions are identified on the endocervix ranging in size from 0.4 x 0.5 x 0.5 cm to 0.6 x 0.6 x 0.6 cm filled with clear gelatinous material. The exocervix is tan in color, smooth and grossly unremarkable. Representative sections are submitted as follows:

- 4A left fallopian tube and left ovary sections taken by research assistant
- 4B right fallopian tube and right ovary sections taken by research assistant
- 4C endometrial tumor sections taken by research assistant
- 4D-4E right fallopian tube serially sectioned and submitted in toto
- 4F-4G right ovary serially sectioned and submitted in toto
- 4H-4I left fallopian tube serially sectioned and submitted in toto
- 4J-4K left ovary serially sectioned and submitted in toto
- 4L-4N anterior endomyometrium superior aspect full thickness
- 4O-4Q anterior endomyometrium midsuperior aspect to cervix longitudinal section
- 4R-4S additional representative section lesion taken from the anterior endometrium
- 4T-4U posterior endomyometrium superior aspect full thickness
- 4V-4X posterior endomyometrium midsuperior aspect to cervix longitudinal section
- 4Y additional representative section lesion taken from the posterior endometrium

5. The specimen container labelled with the patient's name and as "left pelvic lymph nodes" contains multiple pieces of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 0.4 x 0.6 x 0.6 to 1.8 x 1.3 x 0.8 cm. Within the fatty tissue, one lymph node is identified measuring 0.8 x 0.5 x 0.4 cm.

5A one lymph node bisected

5B-5D two nodes and the rest of the fibroadipose tissue submitted in toto

Source: NCI Genomic Data Commons file 5d57add8-c83d-4650-b5a0-fcf0809ed0b1 (TCGA-EO-A2CG.CAF671DB-2DD1-43D5-99C8-185253775B37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).